Somatic mutation profile of tumor specimen MMRF_1988_1_BM_CD138pos (aliquot MMRF_1988_1_BM_CD138pos_T1_KHS5U_L14855) from MMRF case MMRF_1988, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 73.4 years (26,816 days).
Specimen MMRF_1988_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7d8e0009-6257-47c4-b7ad-6e0c984086b8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1988_1_PB_WBC (Blood Derived Normal), aliquot MMRF_1988_1_PB_WBC_C3_KHS5U_L14856; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c9b4dd70-4e82-4cb3-a72c-7990118fa33d

The open-access MAF lists 183 somatic variants for this specimen: 66 protein-altering or splice-affecting, 20 silent, 97 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 55, Missense Mutation 52, Silent 20, Intron 17, 5'UTR 14, Nonsense Mutation 5, 5'Flank 4, 3'Flank 4, Splice Site 3, RNA 3, Frame Shift Del 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 63/417 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CELA3A | c.769T>G p.S257A | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as COSV99266368; called by muse, mutect2, varscan2
- COL4A1 | c.4712C>A p.P1571H | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101011384; called by muse, mutect2, varscan2
- FAT1 | c.10315G>A p.V3439I | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs201982861, COSV71675930, COSV71676690; called by muse, mutect2, varscan2
- H1-4 | c.134C>T p.T45I | Missense Mutation (SNP) | VAF 25/201 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.246); catalogued as rs138821617; called by muse, mutect2, varscan2
- IGHV2-70 | c.271T>A p.S91T | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs376116814; called by muse, varscan2
- IGHV2-70 | c.169T>G p.W57G | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as rs749669763; called by muse, varscan2
- IGKV4-1 | c.358A>C p.T120P | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs192141151; called by muse, mutect2, varscan2
- IGLV3-1 | c.113G>A p.S38N | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs61736462; called by muse, varscan2
- IGLV3-25 | c.214A>G p.R72G | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.109); catalogued as rs755938259; called by muse, varscan2
- IL5RA | c.86C>A p.S29* | Nonsense Mutation (SNP) | VAF 13/121 reads (11%) | catalogued as COSV56524658; called by muse, mutect2, varscan2
- KMT2E | c.1465C>T p.R489W | Missense Mutation (SNP) | VAF 14/145 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs749233634; called by muse, mutect2, varscan2
- MYBPC2 | c.1237C>A p.Q413K | Missense Mutation (SNP) | VAF 22/251 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1156456682; called by muse, mutect2
- MYO1E | c.1670G>A p.R557H | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs775776382, COSV55686499; called by muse, mutect2, varscan2
- PHOSPHO1 | c.100G>T p.D34Y | Missense Mutation (SNP) | VAF 24/163 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV56801081; called by muse, mutect2, varscan2
- PKD1L1 | c.4508C>T p.A1503V | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs201706320, COSV56975347, COSV56975391; called by muse, mutect2, varscan2
- RP2 | c.152G>T p.G51V | Missense Mutation (SNP) | VAF 23/205 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.11); catalogued as rs781992752; called by muse, mutect2, varscan2
- RTP2 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 30/185 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.072); catalogued as rs1553830148, COSV64078914; called by muse, mutect2, varscan2
- SUN3 | c.130C>T p.R44* | Nonsense Mutation (SNP) | VAF 13/56 reads (23%) | catalogued as rs770500301; called by muse, mutect2, varscan2
- TLE2 | c.256G>T p.G86C | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.673); catalogued as rs780015553; called by muse, mutect2, varscan2
- ZBTB5 | c.544C>T p.R182C | Missense Mutation (SNP) | VAF 30/184 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); catalogued as rs747980674, COSV100312657; called by muse, mutect2, varscan2
- AAAS | c.83G>T p.G28V | Missense Mutation (SNP) | VAF 42/157 reads (27%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- ADCY3 | c.2539T>C p.F847L | Missense Mutation (SNP) | VAF 55/270 reads (20%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRF3 | c.1174G>A p.A392T (on ENST00000311519 / NM_001145168.1; = p.A193T on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.99); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- AHNAK | c.7876G>A p.D2626N | Missense Mutation (SNP) | VAF 15/433 reads (3%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.775); called by muse, mutect2
- ALAS2 | c.791_792del p.S264Yfs*30 | Frame Shift Del (DEL) | VAF 14/64 reads (22%) | called by pindel, varscan2
- ANKRD63 | c.496C>T p.H166Y | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.06); called by muse, mutect2, varscan2
- ARHGAP10 | c.2317G>T p.G773C | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP8B4 | c.2590T>C p.W864R | Missense Mutation (SNP) | VAF 32/173 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BEND5 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- C1QL4 | c.640C>G p.L214V | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLK1 | c.829_832del p.N277Ffs*7 | Frame Shift Del (DEL) | VAF 9/60 reads (15%) | called by mutect2, pindel, varscan2
- CLPTM1L | c.1146+2T>C p.X382_splice | Splice Site (SNP) | VAF 43/110 reads (39%) | called by muse, mutect2, varscan2
- CNOT1 | c.5054G>C p.R1685T | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- CYLD | c.505G>T p.E169* | Nonsense Mutation (SNP) | VAF 53/162 reads (33%) | called by muse, mutect2, varscan2
- DDX60 | c.2813G>T p.W938L | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FLNC | c.5933C>T p.T1978I | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- FUT5 | c.249G>A p.W83* | Nonsense Mutation (SNP) | VAF 39/293 reads (13%) | called by muse, mutect2, varscan2
- GCNT3 | c.354G>T p.K118N | Missense Mutation (SNP) | VAF 24/258 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.437); called by muse, mutect2
- GSPT2 | c.160G>A p.V54I | Missense Mutation (SNP) | VAF 70/236 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- HMCN1 | c.10897G>A p.V3633M | Missense Mutation (SNP) | VAF 36/213 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HPRT1 | c.303A>T p.R101S | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- HSPA2 | c.472G>T p.A158S | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGHV1-69D | c.234C>G p.N78K | Missense Mutation (SNP) | VAF 52/210 reads (25%) | SIFT tolerated (0.66); PolyPhen benign (0.003); called by muse, varscan2
- IL17REL | c.674C>A p.P225H | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIFC2 | c.1823_1843del p.L608_P614del | In Frame Del (DEL) | VAF 12/64 reads (19%) | called by pindel, varscan2
- KLK5 | c.449A>G p.H150R | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2
- LINGO2 | c.1757dup p.N586Kfs*39 | Frame Shift Ins (INS) | VAF 35/256 reads (14%) | called by mutect2, pindel, varscan2
- LRGUK | c.1382T>C p.V461A | Missense Mutation (SNP) | VAF 14/189 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.872); called by muse, mutect2
- LRRC74B | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 13/75 reads (17%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- MMRN2 | c.1385A>T p.E462V | Missense Mutation (SNP) | VAF 44/135 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- MUC6 | c.2927T>C p.L976P | Missense Mutation (SNP) | VAF 56/242 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MYH1 | c.5254G>A p.A1752T | Missense Mutation (SNP) | VAF 21/183 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- MYO1C | c.664C>A p.L222M (on ENST00000648651 / NM_001080779.2; = p.L187M on NM_033375.5) | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- NDUFS1 | c.872+2T>G p.X291_splice | Splice Site (SNP) | VAF 26/154 reads (17%) | called by muse, mutect2, varscan2
- OSR1 | c.475G>T p.E159* | Nonsense Mutation (SNP) | VAF 33/203 reads (16%) | called by muse, mutect2, varscan2
- RCN3 | c.356G>C p.S119T | Missense Mutation (SNP) | VAF 34/174 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RPN2 | c.1793A>C p.N598T | Missense Mutation (SNP) | VAF 28/203 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SERPINA11 | c.859G>T p.V287L | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- SLC16A7 | c.219T>G p.G73= | Splice Region (SNP) | VAF 40/212 reads (19%) | called by muse, mutect2, varscan2
- SLC35E4 | c.551C>T p.T184I | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TLR3 | c.2121G>A p.M707I | Missense Mutation (SNP) | VAF 22/242 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- URI1 | c.368-1G>T p.X123_splice | Splice Site (SNP) | VAF 14/98 reads (14%) | called by muse, mutect2, varscan2
- WDR87 | c.263A>C p.D88A | Missense Mutation (SNP) | VAF 48/249 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZBTB8B | c.266A>C p.D89A | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- ZNF423 | c.175C>A p.Q59K (on ENST00000563137 / NM_001379286.1; = p.Q51K on NM_015069.4) | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCL15 | c.324G>T p.L108= | Silent (SNP) | VAF 22/167 reads (13%) | called by muse, mutect2, varscan2
- CIITA | c.1545C>T p.C515= | Silent (SNP) | VAF 41/169 reads (24%) | catalogued as rs200146904, COSV60856859; called by muse, mutect2, varscan2
- CPNE4 | c.1506C>T p.I502= | Silent (SNP) | VAF 33/137 reads (24%) | called by muse, mutect2, varscan2
- DTNB | c.1416A>C p.A472= | Silent (SNP) | VAF 9/53 reads (17%) | called by muse, mutect2, varscan2
- FAM71D | c.996C>T p.V332= | Silent (SNP) | VAF 24/95 reads (25%) | called by muse, varscan2
- FHAD1 | c.1887G>T p.L629= | Silent (SNP) | VAF 8/180 reads (4%) | called by muse, mutect2
- GOLGA4 | c.2091A>G p.L697= | Silent (SNP) | VAF 33/174 reads (19%) | called by muse, mutect2, varscan2
- HELZ2 | c.6756C>T p.S2252= (on ENST00000467148 / NM_001037335.2; = p.S1683= on NM_033405.3) | Silent (SNP) | VAF 23/100 reads (23%) | catalogued as rs756171275; called by muse, mutect2, varscan2
- IGLL5 | c.111C>T p.G37= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs778053128, COSV73250843; called by muse, mutect2, varscan2
- LGALS1 | c.153C>T p.N51= | Silent (SNP) | VAF 25/204 reads (12%) | catalogued as rs551935014; called by muse, mutect2, varscan2
- MYH3 | c.3084G>T p.L1028= | Silent (SNP) | VAF 24/117 reads (21%) | called by muse, mutect2, varscan2
- NOX4 | c.732A>T p.S244= | Silent (SNP) | VAF 25/132 reads (19%) | called by muse, mutect2, varscan2
- OR2T2 | c.348G>A p.L116= | Silent (SNP) | VAF 37/264 reads (14%) | catalogued as rs1266641056, COSV61617795, COSV61618479; called by muse, mutect2, varscan2
- PLA2G4C | c.1398T>C p.H466= | Silent (SNP) | VAF 23/131 reads (18%) | catalogued as rs778104086, COSV62784382; called by muse, mutect2, varscan2
- SDK1 | c.6147C>A p.T2049= | Silent (SNP) | VAF 12/218 reads (6%) | catalogued as COSV67357505; called by muse, mutect2
- SPTBN2 | c.1773C>T p.S591= | Silent (SNP) | VAF 29/164 reads (18%) | catalogued as rs769837002; called by muse, mutect2, varscan2
- TAS2R1 | c.678G>A p.A226= | Silent (SNP) | VAF 13/170 reads (8%) | catalogued as rs140696180; called by muse, mutect2
- WIZ | c.96T>G p.G32= | Silent (SNP) | VAF 27/158 reads (17%) | catalogued as rs773152707; called by muse, mutect2, varscan2
- ZBTB49 | c.933G>A p.K311= | Silent (SNP) | VAF 30/166 reads (18%) | called by muse, mutect2, varscan2
- ZNF710 | c.1065A>G p.V355= | Silent (SNP) | VAF 29/197 reads (15%) | catalogued as rs914235283; called by muse, mutect2, varscan2
- ABHD17B | c.*1502T>A | 3'UTR (SNP) | VAF 20/107 reads (19%) | called by muse, mutect2, varscan2
- AC112695.1 | n.372T>A | RNA (SNP) | VAF 10/35 reads (29%) | called by muse, mutect2, varscan2
- ACP6 | c.882-79G>A | Intron (SNP) | VAF 10/51 reads (20%) | called by muse, mutect2, varscan2
- ADAMTS12 | c.*1519C>A | 3'UTR (SNP) | VAF 34/160 reads (21%) | called by muse, mutect2, varscan2
- AHRR | c.*2821C>T | 3'UTR (SNP) | VAF 14/111 reads (13%) | called by muse, mutect2, varscan2
- AMACR | c.*962C>G | 3'UTR (SNP) | VAF 20/94 reads (21%) | called by muse, mutect2, varscan2
- ANGPT1 | c.*243G>A | 3'UTR (SNP) | VAF 6/94 reads (6%) | called by muse, mutect2
- ANOS1 | c.*822T>C | 3'UTR (SNP) | VAF 91/333 reads (27%) | called by muse, mutect2, varscan2
- ARPP21 | c.1644+899A>C | Intron (SNP) | VAF 17/133 reads (13%) | called by muse, mutect2, varscan2
- ATP7B | c.2355+92C>A | Intron (SNP) | VAF 4/22 reads (18%) | called by mutect2, varscan2
- C2orf80 | c.-89C>A | 5'UTR (SNP) | VAF 42/211 reads (20%) | catalogued as COSV100378752; called by muse, mutect2, varscan2
- CACHD1 | c.*807G>A | 3'UTR (SNP) | VAF 8/42 reads (19%) | called by muse, mutect2, varscan2
- CASP10 | c.1415+9077A>G | Intron (SNP) | VAF 11/106 reads (10%) | catalogued as COSV53780300; called by muse, mutect2, varscan2
- CCNQ | c.*205G>A | 3'UTR (SNP) | VAF 28/152 reads (18%) | catalogued as rs1557024892, COSV52344735; called by muse, mutect2, varscan2
- CD109 | c.*194G>A | 3'UTR (SNP) | VAF 7/31 reads (23%) | called by muse, mutect2, varscan2
- CDC42BPA | c.-68T>G | 5'UTR (SNP) | VAF 50/172 reads (29%) | called by muse, mutect2, varscan2
- CDH2 | c.*1002del | 3'UTR (DEL) | VAF 8/40 reads (20%) | called by mutect2, varscan2
- CDRT15P2 | n.344T>A | RNA (SNP) | VAF 32/103 reads (31%) | called by muse, mutect2, varscan2
- CENPP | c.*3797A>C | 3'UTR (SNP) | VAF 65/195 reads (33%) | called by muse, mutect2, varscan2
- CLASP1 | c.*17T>C | 3'UTR (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2, varscan2
- CNOT6L | c.*489C>A | 3'UTR (SNP) | VAF 53/194 reads (27%) | called by muse, mutect2, varscan2
- CORO1C | c.*1967G>A | 3'UTR (SNP) | VAF 18/75 reads (24%) | catalogued as rs189071650; called by muse, mutect2, varscan2
- CSNK1A1 | c.*1095T>C | 3'UTR (SNP) | VAF 11/36 reads (31%) | catalogued as rs1003792213, COSV99939235; called by muse, mutect2, varscan2
- CST9LP1 | n.228C>T | RNA (SNP) | VAF 20/87 reads (23%) | called by muse, mutect2, varscan2
- DIP2C | c.*2378_*2381del | 3'UTR (DEL) | VAF 15/79 reads (19%) | catalogued as rs760190787; called by mutect2, pindel, varscan2
- EFNB1 | c.-506G>A | 5'UTR (SNP) | VAF 19/125 reads (15%) | called by muse, mutect2, varscan2
- EPHA5 | c.-269A>C | 5'UTR (SNP) | VAF 12/85 reads (14%) | called by muse, mutect2, varscan2
- ETS1 | c.*283del | 3'UTR (DEL) | VAF 17/151 reads (11%) | called by mutect2, pindel, varscan2
- EXTL3 | c.-292A>G | 5'UTR (SNP) | VAF 6/110 reads (5%) | called by muse, mutect2
- FAM155B | c.*1548C>T | 3'UTR (SNP) | VAF 34/154 reads (22%) | called by muse, mutect2, varscan2
- FLRT2 | c.*3550C>T | 3'UTR (SNP) | VAF 10/62 reads (16%) | called by muse, mutect2, varscan2
- FUCA1 | c.*558A>T | 3'UTR (SNP) | VAF 16/95 reads (17%) | called by muse, mutect2, varscan2
- GABRE | c.784+1181G>C | Intron (SNP) | VAF 20/61 reads (33%) | called by muse, mutect2, varscan2
- GCSAM | c.-45G>T | 5'UTR (SNP) | VAF 31/379 reads (8%) | called by muse, mutect2
- GRK7 | c.*401del | 3'UTR (DEL) | VAF 20/91 reads (22%) | catalogued as rs548593246; called by mutect2, pindel, varscan2
- HINT2 | c.400+17C>A | Intron (SNP) | VAF 20/163 reads (12%) | called by muse, mutect2, varscan2
- IGLL5 | c.-98T>C | 5'UTR (SNP) | VAF 19/68 reads (28%) | called by muse, mutect2, varscan2
- IL1RAPL1 | c.*411G>T | 3'UTR (SNP) | VAF 26/109 reads (24%) | called by muse, mutect2, varscan2
- KCNA4 | c.*49T>G | 3'UTR (SNP) | VAF 49/123 reads (40%) | called by muse, mutect2, varscan2
- KCNAB1 | c.*584C>T | 3'UTR (SNP) | VAF 10/42 reads (24%) | called by muse, mutect2, varscan2
- LILRA1 | c.*319C>G | 3'UTR (SNP) | VAF 46/534 reads (9%) | called by muse, mutect2
- LILRB5 | c.34+33G>A | Intron (SNP) | VAF 31/388 reads (8%) | catalogued as rs753167771; called by muse, mutect2
- LRRC37A5P | n.251-3942G>C | Intron (SNP) | VAF 11/255 reads (4%) | called by muse, mutect2
- LUZP2 | c.*230A>C | 3'UTR (SNP) | VAF 55/132 reads (42%) | called by muse, mutect2, varscan2
- LY75 | c.-21del | 5'UTR (DEL) | VAF 9/46 reads (20%) | called by mutect2, pindel, varscan2
- MAPKAP1 | c.*791C>T | 3'UTR (SNP) | VAF 26/250 reads (10%) | catalogued as rs937885039; called by muse, mutect2
- MAPT | c.220+2491C>T | Intron (SNP) | VAF 26/185 reads (14%) | catalogued as rs780582778, CM111323, COSV52245304; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MBNL1 | c.-909C>T | 5'UTR (SNP) | VAF 8/202 reads (4%) | called by muse, mutect2
- MBP | c.*1243G>A | 3'UTR (SNP) | VAF 27/140 reads (19%) | called by muse, mutect2, varscan2
- MEGF10 | c.*2693C>T | 3'UTR (SNP) | VAF 12/100 reads (12%) | called by muse, mutect2, varscan2
- MEIOC | c.*194C>T | 3'UTR (SNP) | VAF 4/32 reads (13%) | called by mutect2, varscan2
- MIRLET7A3 | chr22:46109902 C>T | 5'Flank (SNP) | VAF 6/150 reads (4%) | called by muse, mutect2
- MTMR6 | c.-286G>A | 5'UTR (SNP) | VAF 6/132 reads (5%) | called by muse, mutect2
- MYO9A | c.*3402C>T | 3'UTR (SNP) | VAF 9/103 reads (9%) | called by muse, mutect2
- NDUFB2 | c.*29+114T>A | Intron (SNP) | VAF 65/292 reads (22%) | called by muse, mutect2, varscan2
- NETO1 | c.469+23776del | Intron (DEL) | VAF 13/51 reads (25%) | called by mutect2, pindel, varscan2
- NGDN | c.*96G>C | 3'UTR (SNP) | VAF 12/72 reads (17%) | called by muse, mutect2, varscan2
- NGDN | chr14:23478408 G>T | 3'Flank (SNP) | VAF 9/81 reads (11%) | called by muse, mutect2, varscan2
- NGDN | chr14:23478538 G>C | 3'Flank (SNP) | VAF 11/117 reads (9%) | called by muse, mutect2, varscan2
- NGDN | chr14:23478674 G>C | 3'Flank (SNP) | VAF 8/109 reads (7%) | called by muse, mutect2
- NOP16 | chr5:176388655 G>T | 5'Flank (SNP) | VAF 37/141 reads (26%) | called by muse, mutect2, varscan2
- NOP53 | c.599-64G>C | Intron (SNP) | VAF 10/97 reads (10%) | called by muse, mutect2
- NRK | c.*1093A>T | 3'UTR (SNP) | VAF 23/64 reads (36%) | called by muse, mutect2, varscan2
- PAX5 | c.-11G>A | 5'UTR (SNP) | VAF 23/93 reads (25%) | called by muse, mutect2, varscan2
- PCDH15 | c.*683C>T | 3'UTR (SNP) | VAF 19/88 reads (22%) | called by muse, mutect2, varscan2
- PCDH18 | c.*49C>A | 3'UTR (SNP) | VAF 16/142 reads (11%) | called by muse, varscan2
- PKP2 | c.*440G>A | 3'UTR (SNP) | VAF 82/179 reads (46%) | called by muse, mutect2, varscan2
- PRL | chr6:22297231 G>T | 5'Flank (SNP) | VAF 10/70 reads (14%) | called by muse, mutect2, varscan2
- QKI | c.1010-883_1010-871del | Intron (DEL) | VAF 9/47 reads (19%) | called by mutect2, pindel
- RAD52 | c.*421C>A | 3'UTR (SNP) | VAF 13/58 reads (22%) | called by muse, mutect2, varscan2
- RGS5 | c.*3855A>C | 3'UTR (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- RIC1 | c.*60T>C | 3'UTR (SNP) | VAF 38/171 reads (22%) | catalogued as rs1282242052; called by muse, mutect2, varscan2
- RICTOR | c.4633+23C>T | Intron (SNP) | VAF 9/163 reads (6%) | called by muse, mutect2
- RNF166 | c.*822A>G | 3'UTR (SNP) | VAF 13/55 reads (24%) | called by muse, mutect2, varscan2
- RNF182 | c.-152A>T | 5'UTR (SNP) | VAF 19/132 reads (14%) | called by muse, mutect2, varscan2
- SCAF11 | c.842-225C>T | Intron (SNP) | VAF 6/29 reads (21%) | called by muse, mutect2, varscan2
- SCTR | c.194-50C>A | Intron (SNP) | VAF 19/80 reads (24%) | called by muse, mutect2, varscan2
- SF3B2 | c.549+158G>A | Intron (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- SLC25A3 | c.*246_*249del | 3'UTR (DEL) | VAF 21/97 reads (22%) | called by mutect2, pindel, varscan2
- SLC29A2 | c.*292C>A | 3'UTR (SNP) | VAF 14/359 reads (4%) | called by muse, mutect2
- SLC9A6 | c.*660G>A | 3'UTR (SNP) | VAF 17/84 reads (20%) | called by muse, mutect2, varscan2
- SRGAP1 | c.*3715del | 3'UTR (DEL) | VAF 4/34 reads (12%) | catalogued as rs1555178267; called by pindel, varscan2
- SRSF6 | c.*786A>G | 3'UTR (SNP) | VAF 16/95 reads (17%) | called by muse, mutect2, varscan2
- ST8SIA2 | c.*4218T>C | 3'UTR (SNP) | VAF 28/159 reads (18%) | called by muse, mutect2, varscan2
- STPG2 | c.*2115A>T | 3'UTR (SNP) | VAF 6/20 reads (30%) | called by muse, mutect2, varscan2
- TEKT5 | c.*15C>T | 3'UTR (SNP) | VAF 31/196 reads (16%) | catalogued as rs377045118; called by muse, mutect2, varscan2
- TFAP2C | c.*826C>T | 3'UTR (SNP) | VAF 23/81 reads (28%) | catalogued as rs1428042188; called by muse, mutect2, varscan2
- TNFRSF1A | c.*188G>A | 3'UTR (SNP) | VAF 40/108 reads (37%) | catalogued as rs1361035906; called by muse, mutect2, varscan2
- TRIM44 | c.-334G>A | 5'UTR (SNP) | VAF 9/21 reads (43%) | called by muse, mutect2
- UNC45B | c.*685G>A | 3'UTR (SNP) | VAF 17/80 reads (21%) | called by muse, mutect2, varscan2
- VAMP7 | c.*1006C>A | 3'UTR (SNP) | VAF 10/174 reads (6%) | called by muse, mutect2
- VWA5A | chr11:124147344 G>C | 3'Flank (SNP) | VAF 46/116 reads (40%) | called by muse, mutect2, varscan2
- WNT7A | c.*1304G>A | 3'UTR (SNP) | VAF 14/194 reads (7%) | called by muse, mutect2
- ZDHHC22 | c.*1919C>T | 3'UTR (SNP) | VAF 13/104 reads (13%) | catalogued as rs968896675; called by muse, mutect2, varscan2
- ZNF236 | c.*3C>T | 3'UTR (SNP) | VAF 18/78 reads (23%) | catalogued as rs765702259, COSV99471015; called by muse, mutect2, varscan2
- ZNF317 | c.-263G>T | 5'UTR (SNP) | VAF 29/220 reads (13%) | called by muse, mutect2, varscan2
- ZNF774 | chr15:90349079 C>T | 5'Flank (SNP) | VAF 32/163 reads (20%) | catalogued as rs1388581722; called by muse, mutect2
